Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-AAXN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-AAXN-01A (Primary Tumor).

SPEC #: Status: Obtained: Received:

CLINICAL HISTORY:

SUCCEED; 233.1

SPECIMEN/PROCEDURE:

1. CERVIX - 12:00
2. LYMPH NODE, ILIAC - LEFT EXTERNAL

IMPRESSION:

- 1) CERVICAL BIOPSY AT 12 O'CLOCK:
Squamous cell carcinoma, large cell nonkeratinizing with stromal invasion.
- 2) LEFT EXTERNAL ILIAC LYMPH NODES:
Squamous cell carcinoma, consistent with metastasis from cervical primary.

Dictated by:

Entered:

GROSS DESCRIPTION:

1. Received in formalin labeled with the patient's name and cervix 12 o'clock. Received are 2 pale pink to pale tan slightly hemorrhagic tissue fragments ranging from 0.7 to 1 cm in greatest dimension. The specimen is entirely submitted in one cassette.
2. Received in formalin labeled "left external iliac lymph node" and with the patient's name, 1 grey-tan granular partially encapsulated portion of lymph node, 1.4 x 1 x 1.2 cm. The specimen is trisected and entirely submitted in one cassette.

Dictated by:

Entered:

CPT Codes:

PATHOLOGY TISSUE, CERVICAL BIOPSY/88305

ICD9 Codes:

180.9

ICD-O-3
Carcinoma, squamous cell, large cell,
non keratinizing NOS 8072/3
Site: Cervix NOS C53.9
JW 6/3/14

Electronically Signed by:

** END OF REPORT **

HIFAA Discrepancy		

Source: NCI Genomic Data Commons file 21d93de5-8d2e-4145-8063-dc65a48a6d87 (TCGA-ZJ-AAXN.33662E91-6459-47D9-858A-243D8E54EB63.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).